Somatic mutation profile of tumor specimen TCGA-DA-A3F3-06A (aliquot TCGA-DA-A3F3-06A-11D-A20D-08) from TCGA case TCGA-DA-A3F3, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 53.2 years (19,436 days).
Specimen TCGA-DA-A3F3-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4f547eb6-d4ab-4e4b-8e87-252dd43d3f52.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DA-A3F3-10A (Blood Derived Normal), aliquot TCGA-DA-A3F3-10A-01D-A20D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a7b00f0b-13a4-4975-8a3e-34341d5c9511

The open-access MAF lists 353 somatic variants for this specimen: 247 protein-altering or splice-affecting, 98 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 226, Silent 98, Nonsense Mutation 13, Frame Shift Del 3, 5'Flank 3, Splice Site 2, Splice Region 2, Intron 2, RNA 2, In Frame Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 85/230 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 85/234 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ABI3BP | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV52551045; called by muse, mutect2, varscan2
- AC008397.2 | c.1840G>A p.D614N | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53208076; called by muse, mutect2, varscan2
- AC126283.2 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as rs1355835737, COSV67099135; called by muse, mutect2, varscan2
- ACHE | c.806C>T p.T269M | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs775312669, COSV53821463; called by muse, mutect2, varscan2
- ADAMTS19 | c.2986C>T p.R996* | Nonsense Mutation (SNP) | VAF 43/268 reads (16%) | catalogued as rs747600290, COSV50796775; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4120G>C p.G1374R | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54455519; called by muse, mutect2, varscan2
- ADCY1 | c.1249G>A p.D417N | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52031045; called by muse, mutect2, varscan2
- ADGRF5 | c.2556G>T p.Q852H | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV51936347; called by muse, mutect2, varscan2
- ADGRV1 | c.12676G>A p.D4226N | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs747891433, COSV67995124; called by muse, mutect2, varscan2
- AK8 | c.565C>T p.H189Y | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53754248; called by muse, mutect2, varscan2
- AKAP6 | c.3772G>A p.D1258N | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as COSV55219924; called by muse, mutect2, varscan2
- ANAPC7 | c.1114A>G p.S372G | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.52); PolyPhen benign (0.058); catalogued as rs375151847; called by muse, mutect2, varscan2
- ANGPT4 | c.1496G>A p.R499Q | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1385108123, COSV67922092; called by muse, mutect2, varscan2
- ANK3 | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1290278926, COSV55055997; called by muse, mutect2, varscan2
- ANKRD46 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.664); catalogued as rs267601678, COSV59513939, COSV59514594; called by muse, mutect2, varscan2
- APBB1 | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); catalogued as COSV54973951; called by muse, mutect2, varscan2
- APBB1IP | c.1141T>C p.C381R | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66136150; called by muse, mutect2, varscan2
- ARAP2 | c.2932G>A p.E978K | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs758617625, COSV58287623; called by muse, mutect2, varscan2
- ARHGAP25 | c.1441G>A p.E481K (on ENST00000409202 / NM_001007231.3; = p.E473K on NM_014882.3) | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.202); catalogued as rs767315911, COSV54904499; called by muse, mutect2, varscan2
- ATF5 | c.281C>T p.T94I | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV100352412, COSV61313627; called by muse, mutect2, varscan2
- ATF6 | c.1652G>C p.S551T | Missense Mutation (SNP) | VAF 46/201 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.056); catalogued as COSV63408349; called by muse, mutect2, varscan2
- AZU1 | c.583G>A p.G195S | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs771828264, COSV52142605; called by muse, mutect2, varscan2
- BPTF | c.7015C>T p.P2339S | Missense Mutation (SNP) | VAF 42/163 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.102); catalogued as COSV58840441; called by muse, mutect2, varscan2
- BSN | c.6602C>T p.P2201L | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56527096; called by muse, mutect2, varscan2
- C10orf71 | c.1385G>A p.S462N | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as COSV60512987; called by muse, mutect2, varscan2
- C2orf42 | c.1459C>T p.R487C | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs146789788, COSV52451747; called by muse, mutect2, varscan2
- C6 | c.95G>A p.W32* | Nonsense Mutation (SNP) | VAF 23/59 reads (39%) | catalogued as COSV54710629; called by muse, mutect2, varscan2
- C8B | c.593G>A p.G198D | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64778334; called by muse, mutect2, varscan2
- CA1 | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 58/84 reads (69%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56279142; called by muse, mutect2, varscan2
- CAMK2D | c.497G>C p.G166A | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs1231440552, COSV56433938; called by muse, mutect2, varscan2
- CASQ1 | c.233A>C p.D78A | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.262); catalogued as COSV63624531; called by muse, mutect2, varscan2
- CASR | c.1823G>A p.G608D (on ENST00000490131; = p.G685D on NM_000388.4) | Missense Mutation (SNP) | VAF 47/91 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as COSV56141357; called by muse, mutect2, varscan2
- CATSPERB | c.2117G>A p.R706K | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56429178; called by muse, mutect2, varscan2
- CATSPERG | c.1568C>T p.S523L | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs140177794, COSV53048178; called by muse, mutect2, varscan2
- CCND2 | c.599C>T p.S200L | Missense Mutation (SNP) | VAF 76/229 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54223253; called by muse, mutect2, varscan2
- CD177 | c.499G>A p.G167R | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.845); catalogued as rs1307558005, COSV100946038; called by muse, varscan2
- CD177 | c.500G>A p.G167E | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.781); catalogued as rs775597706, COSV65122627; called by muse, varscan2
- CD1C | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 280/407 reads (69%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV63806251; called by muse, mutect2, varscan2
- CDH10 | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 57/132 reads (43%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.638); catalogued as rs753331850, COSV52578042; called by muse, mutect2, varscan2
- CELSR3 | c.6683G>A p.R2228Q | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.094); catalogued as rs1477034170, COSV50841186; called by muse, mutect2, varscan2
- CEP85 | c.1351C>T p.R451C | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1193239293, COSV53330660; called by muse, mutect2, varscan2
- CFHR1 | c.401G>A p.W134* | Nonsense Mutation (SNP) | VAF 74/80 reads (93%) | catalogued as rs1296094673, COSV57627849; called by muse, mutect2, varscan2
- CHL1 | c.1703+1G>T p.X568_splice (on ENST00000397491 / NM_001253387.1; = p.X584_splice on NM_006614.4) | Splice Site (SNP) | VAF 16/24 reads (67%) | catalogued as COSV56597197; called by muse, mutect2, varscan2
- CHL1 | c.2687A>C p.N896T (on ENST00000397491 / NM_001253387.1; = p.N912T on NM_006614.4) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV56606016; called by muse, mutect2, varscan2
- CHRNA4 | c.1541A>G p.N514S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV64721075; called by muse, mutect2, varscan2
- CNGA2 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 61/73 reads (84%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.118); catalogued as rs761937144, COSV61704739; called by muse, mutect2, varscan2
- CNGA2 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 62/74 reads (84%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs1569427566; called by muse, mutect2, varscan2
- CNTN1 | c.998G>A p.W333* | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | catalogued as COSV61641766; called by muse, mutect2, varscan2
- COL4A4 | c.2675C>T p.P892L | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.011); catalogued as COSV61631048; called by muse, mutect2, varscan2
- CORO2A | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV59663690; called by muse, mutect2, varscan2
- CPED1 | c.2101C>T p.P701S | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV60006191; called by muse, mutect2, varscan2
- CSMD2 | c.5692C>G p.H1898D | Missense Mutation (SNP) | VAF 98/228 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV53927911; called by muse, mutect2, varscan2
- CSRNP1 | c.1705C>T p.P569S | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.303); catalogued as COSV56187674; called by muse, mutect2, varscan2
- CUZD1 | c.1718C>T p.S573F | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs753825900, COSV59026030; called by muse, mutect2, varscan2
- DAB1 | c.1152G>T p.Q384H (on ENST00000371231; = p.Q351H on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/118 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100976327, COSV64694348; called by muse, mutect2, varscan2
- DAND5 | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 70/176 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.69); catalogued as COSV100397359; called by muse, mutect2, varscan2
- DGKK | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as rs376014418, COSV65707507; called by muse, mutect2, varscan2
- DNAH10 | c.7319G>A p.G2440E (on ENST00000409039; = p.G2379E on NM_207437.3) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs1566018998, COSV69001266; called by muse, mutect2, varscan2
- DNAH3 | c.6632C>T p.S2211F | Missense Mutation (SNP) | VAF 71/155 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1338573599, COSV54531613; called by muse, mutect2, varscan2
- DNAH5 | c.3544G>A p.E1182K | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs868077328, COSV54224694; called by muse, mutect2, varscan2
- DNAJC11 | c.611C>T p.S204L | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs1384840539, COSV53790478; called by muse, mutect2, varscan2
- DOLPP1 | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 303/722 reads (42%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV59910956; called by muse, mutect2, varscan2
- DPYD | c.2617G>A p.D873N | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV64603969; called by muse, mutect2, varscan2
- DYTN | c.1352G>A p.R451Q | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as rs565968460, COSV71753006; called by muse, mutect2, varscan2
- EFCAB13 | c.2338G>A p.D780N | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.75); PolyPhen benign (0.019); catalogued as rs959842039, COSV58949966; called by muse, mutect2, varscan2
- EGF | c.3395G>A p.R1132K | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.024); catalogued as COSV54480785; called by muse, mutect2, varscan2
- EGFR | c.1810A>G p.N604D | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV51816429; called by muse, mutect2, varscan2
- ENAM | c.713C>T p.P238L | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV68536382; called by muse, mutect2, varscan2
- ENC1 | c.1064C>T p.S355L | Missense Mutation (SNP) | VAF 180/328 reads (55%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.449); catalogued as rs1170881363, COSV56631221; called by muse, mutect2, varscan2
- ENOX1 | c.1507G>A p.E503K | Missense Mutation (SNP) | VAF 49/77 reads (64%) | SIFT tolerated (0.33); PolyPhen benign (0.358); catalogued as COSV54905842; called by muse, mutect2, varscan2
- ESF1 | c.2269G>C p.V757L | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as COSV52522329; called by muse, mutect2, varscan2
- ESYT1 | c.1747C>T p.P583S | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as rs1383367660, COSV57274496; called by muse, mutect2, varscan2
- EYA4 | c.1254G>A p.M418I (on ENST00000531901 / NM_001301013.1; = p.M412I on NM_004100.5) | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV62046235; called by muse, mutect2, varscan2
- EYS | c.1741T>A p.C581S | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV100676584, COSV60991204; called by muse, mutect2, varscan2
- FAM117A | c.451C>T p.H151Y | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV53632698; called by muse, mutect2, varscan2
- FAM184A | c.766C>T p.Q256* | Nonsense Mutation (SNP) | VAF 10/19 reads (53%) | catalogued as COSV58858703; called by muse, mutect2, varscan2
- FBN1 | c.8203G>A p.E2735K | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs756124960, COSV57329343; called by muse, mutect2, varscan2
- FBXO16 | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 28/32 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs367952507; called by muse, mutect2, varscan2
- FBXO38 | c.2711C>T p.S904F (on ENST00000340253 / NM_205836.3; = p.S829F on NM_030793.5) | Missense Mutation (SNP) | VAF 68/73 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57029095; called by muse, mutect2, varscan2
- FCRL6 | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 70/102 reads (69%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.521); catalogued as COSV58941670; called by muse, mutect2, varscan2
- FCRLA | c.1024C>T p.H342Y (on ENST00000367959; = p.H319Y on NM_032738.4) | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV52686330; called by muse, mutect2, varscan2
- FGA | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.942); catalogued as COSV57394682; called by muse, mutect2, varscan2
- FIGNL1 | c.1288T>G p.L430V | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as COSV63553738; called by muse, mutect2, varscan2
- FMN2 | c.3692G>A p.G1231E | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT tolerated, low confidence (0.63); PolyPhen probably damaging (1); catalogued as COSV60418826; called by muse, mutect2
- FNDC3A | c.2609C>T p.P870L (on ENST00000492622 / NM_001079673.2; = p.P814L on NM_014923.5) | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.635); catalogued as COSV68133910; called by muse, mutect2, varscan2
- FRMD5 | c.1301C>T p.P434L | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as COSV68725372; called by muse, mutect2, varscan2
- FRS3 | c.178C>T p.L60F | Missense Mutation (SNP) | VAF 38/52 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52485439; called by muse, mutect2, varscan2
- GBP6 | c.1333G>A p.D445N | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT tolerated (0.37); PolyPhen benign (0.02); catalogued as COSV65012583; called by muse, mutect2, varscan2
- GCK | c.194C>T p.T65I | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as CM032901, COSV61754620; called by muse, mutect2, varscan2
- GDI2 | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66335238; called by muse, mutect2, varscan2
- GHR | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50117975; called by muse, mutect2, varscan2
- GHR | c.1091G>A p.R364K | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); catalogued as COSV50118034, COSV50134231; called by muse, mutect2, varscan2
- GPR3 | c.977C>T p.S326F | Missense Mutation (SNP) | VAF 99/215 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV64995192; called by muse, mutect2, varscan2
- GRIN2D | c.2554C>T p.L852F | Missense Mutation (SNP) | VAF 88/183 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53519483; called by muse, mutect2, varscan2
- GRK5 | c.1535A>G p.Q512R | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64866850; called by muse, mutect2, varscan2
- GRK7 | c.784A>T p.T262S | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV53823762; called by muse, mutect2, varscan2
- HCAR3 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 42/66 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs977516577, COSV63673677; called by muse, mutect2, varscan2
- HGD | c.1307C>T p.P436L | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as COSV52199308; called by muse, mutect2, varscan2
- HPS5 | c.2458C>T p.P820S (on ENST00000349215 / NM_181507.2; = p.P706S on NM_007216.4) | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as COSV61687670; called by muse, mutect2, varscan2
- HSPA5 | c.1313C>T p.P438L | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.493); catalogued as COSV99413332; called by muse, mutect2, varscan2
- IFT122 | c.3038G>A p.R1013K (on ENST00000348417 / NM_052989.3; = p.R954K on NM_018262.4) | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56204810; called by muse, mutect2, varscan2
- IL12RB1 | c.974G>A p.G325D | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59097967; called by muse, mutect2, varscan2
- IL6R | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 67/89 reads (75%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59817425; called by muse, mutect2, varscan2
- INAVA | c.995C>T p.P332L | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV66256068; called by muse, mutect2
- IQCH | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.15); catalogued as rs201543259, COSV60055623; called by muse, mutect2, varscan2
- IQCN | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.17); catalogued as COSV66577705; called by muse, mutect2, varscan2
- IRGC | c.1292G>A p.G431E | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); catalogued as COSV54984965; called by muse, mutect2, varscan2
- IRX6 | c.1117C>T p.P373S | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.47); PolyPhen benign (0.057); catalogued as COSV51861126; called by muse, mutect2, varscan2
- ITM2B | c.640C>T p.H214Y | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as COSV66035051; called by muse, mutect2, varscan2
- KCNT1 | c.796G>A p.G266R (on ENST00000488444; = p.G285R on NM_020822.3) | Missense Mutation (SNP) | VAF 53/112 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.722); catalogued as COSV53704652; called by muse, mutect2, varscan2
- KDF1 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0.023); catalogued as rs748813446, COSV57672138; called by muse, mutect2, varscan2
- KDF1 | c.157C>T p.H53Y | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV57672142; called by muse, mutect2, varscan2
- KIAA0319 | c.449T>C p.L150P | Missense Mutation (SNP) | VAF 81/381 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV65499754; called by muse, mutect2, varscan2
- KIF1C | c.816T>G p.N272K | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57907303; called by muse, mutect2
- KLRF1 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as COSV54380058, COSV54382119; called by muse, mutect2, varscan2
- KNL1 | c.4801C>T p.Q1601* (on ENST00000346991 / NM_170589.5; = p.Q1575* on NM_144508.5) | Nonsense Mutation (SNP) | VAF 27/52 reads (52%) | catalogued as COSV61160250; called by muse, mutect2, varscan2
- KRT3 | c.574G>C p.G192R | Missense Mutation (SNP) | VAF 55/115 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as COSV58817281; called by muse, mutect2, varscan2
- LCT | c.3230G>A p.G1077E | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs370021729; called by muse, mutect2, varscan2
- LIN9 | c.1182G>C p.W394C (on ENST00000366808 / NM_001270410.2; = p.W339C on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs761563689, COSV60245776; called by muse, mutect2, varscan2
- MAMLD1 | c.1433C>T p.S478F | Missense Mutation (SNP) | VAF 50/54 reads (93%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV53380620; called by muse, mutect2, varscan2
- MARCHF10 | c.1960G>A p.E654K | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV60888759; called by muse, mutect2, varscan2
- MECOM | c.1841G>A p.G614E (on ENST00000468789 / NM_001105078.4; = p.G802E on NM_004991.4) | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.113); catalogued as rs139044661, COSV52962683; called by muse, mutect2, varscan2
- MECOM | c.1183G>A p.D395N (on ENST00000468789 / NM_001105078.4; = p.D583N on NM_004991.4) | Missense Mutation (SNP) | VAF 71/107 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV52974299; called by muse, mutect2, varscan2
- MED13L | c.5873C>T p.S1958F | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV56123635; called by muse, mutect2
- MMP20 | c.1354T>A p.Y452N | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.139); catalogued as COSV52776558; called by muse, mutect2, varscan2
- MMP25 | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 94/384 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as rs755060073, COSV60680182; called by muse, mutect2, varscan2
- MRAP | c.341G>A p.G114E | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV57937243; called by muse, mutect2, varscan2
- MTMR10 | c.1889A>G p.Y630C | Missense Mutation (SNP) | VAF 100/236 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV58729834; called by muse, mutect2, varscan2
- MUC4 | c.1556G>A p.G519E | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT tolerated, low confidence (0.95); PolyPhen probably damaging (0.934); catalogued as COSV62154451; called by muse, mutect2, varscan2
- MUC4 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.301); catalogued as COSV62193518; called by muse, mutect2, varscan2
- MYOF | c.2976C>T p.G992= | Splice Region (SNP) | VAF 33/94 reads (35%) | catalogued as COSV63710480; called by muse, mutect2, varscan2
- N4BP2 | c.2171C>T p.S724L | Missense Mutation (SNP) | VAF 51/97 reads (53%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV54703923; called by muse, mutect2, varscan2
- NETO1 | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as rs760230093, COSV55007207; called by muse, mutect2, varscan2
- NGF | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 25/27 reads (93%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV65688430, COSV65688869; called by muse, mutect2, varscan2
- NID2 | c.2285C>T p.P762L | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53498921; called by muse, mutect2, varscan2
- NLRP5 | c.1656G>T p.M552I | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs761012006, COSV66765236, COSV66767256; called by muse, mutect2, varscan2
- NRXN3 | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.268); catalogued as COSV73587333; called by muse, mutect2, varscan2
- NUP107 | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.811); catalogued as COSV57495748; called by muse, mutect2, varscan2
- NUP210 | c.4739C>T p.A1580V | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs1417651636, COSV54408731, COSV99596106; called by muse, mutect2, varscan2
- OGDHL | c.1783G>A p.G595R | Missense Mutation (SNP) | VAF 37/66 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100934578, COSV65103360; called by muse, mutect2, varscan2
- OR1L1 | c.219T>A p.D73E (on ENST00000373686; = p.D23E on NM_001005236.3) | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.038); catalogued as COSV58936720; called by muse, mutect2, varscan2
- OR2L13 | c.695G>A p.G232E | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV63559458; called by muse, mutect2, varscan2
- OR4C12 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.191); catalogued as rs142499788, COSV58859666; called by muse, mutect2, varscan2
- OR52K2 | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs757200117, COSV57835270; called by muse, mutect2, varscan2
- OR5J2 | c.416G>A p.R139K | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.018); catalogued as COSV56622123; called by muse, mutect2, varscan2
- OR8G2P | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 37/40 reads (93%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.454); catalogued as rs769441833; called by muse, mutect2, varscan2
- OTOP3 | c.1471G>A p.A491T | Missense Mutation (SNP) | VAF 64/102 reads (63%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.69); catalogued as COSV60913909; called by muse, mutect2, varscan2
- OVGP1 | c.1532C>T p.S511F | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.012); catalogued as COSV63858931; called by muse, mutect2, varscan2
- PADI2 | c.1687G>A p.E563K | Missense Mutation (SNP) | VAF 97/189 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV64954131; called by muse, mutect2, varscan2
- PALD1 | c.1269G>A p.W423* | Nonsense Mutation (SNP) | VAF 48/118 reads (41%) | catalogued as COSV54975450; called by muse, mutect2, varscan2
- PAPPA2 | c.3568C>T p.Q1190* | Nonsense Mutation (SNP) | VAF 45/63 reads (71%) | catalogued as COSV62811153; called by muse, mutect2, varscan2
- PASD1 | c.2008C>T p.P670S | Missense Mutation (SNP) | VAF 51/58 reads (88%) | SIFT tolerated (0.13); PolyPhen benign (0.094); catalogued as COSV64853891, COSV64854644; called by muse, mutect2, varscan2
- PATJ | c.1727C>T p.S576F | Missense Mutation (SNP) | VAF 73/168 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57165768; called by muse, mutect2, varscan2
- PDE4B | c.1513A>G p.T505A | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV58484160; called by muse, mutect2, varscan2
- PDIK1L | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.435); catalogued as rs1255845219, COSV65322807; called by muse, mutect2, varscan2
- PELI2 | c.1153C>T p.P385S | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.077); catalogued as rs138009911; called by muse, mutect2, varscan2
- PHLPP2 | c.1442C>T p.S481F | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.548); catalogued as rs761074922, COSV62422826; called by muse, mutect2, varscan2
- PKD1L1 | c.1183G>A p.D395N | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.03); catalogued as COSV56970023; called by muse, mutect2, varscan2
- PLCL2 | c.1756G>A p.E586K (on ENST00000615277 / NM_001144382.2; = p.E460K on NM_015184.5) | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV67620530; called by muse, mutect2, varscan2
- PLS1 | c.515C>T p.S172F | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV61834499; called by muse, mutect2, varscan2
- POLQ | c.3118C>T p.R1040* | Nonsense Mutation (SNP) | VAF 7/24 reads (29%) | catalogued as rs764050733, COSV51752379; called by muse, mutect2, varscan2
- POPDC3 | c.332T>A p.L111* | Nonsense Mutation (SNP) | VAF 130/295 reads (44%) | catalogued as COSV54644863; called by muse, mutect2, varscan2
- POSTN | c.1969C>T p.R657C | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.582); catalogued as COSV65712801; called by muse, mutect2, varscan2
- PRB2 | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 117/428 reads (27%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.839); catalogued as COSV66982646; called by muse, varscan2
- PREX2 | c.2404G>A p.D802N | Missense Mutation (SNP) | VAF 96/129 reads (74%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.119); catalogued as COSV55781273; called by muse, mutect2, varscan2
- PRRC2A | c.1816C>T p.P606S | Missense Mutation (SNP) | VAF 433/521 reads (83%) | SIFT tolerated (0.06); PolyPhen benign (0.395); catalogued as rs781644251, COSV65688899; called by muse, mutect2, varscan2
- PSG1 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 53/191 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as rs774631748; called by muse, mutect2, varscan2
- PTPN13 | c.6743C>T p.P2248L (on ENST00000411767 / NM_080683.3; = p.P2229L on NM_006264.3) | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57417177; called by muse, mutect2, varscan2
- PTPRD | c.3073C>T p.H1025Y | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV61938506, COSV61959330; called by muse, mutect2, varscan2
- PTPRD | c.1262C>T p.P421L | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61962769; called by muse, mutect2, varscan2
- PTPRD | c.1261C>T p.P421S | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV61963316; called by muse, mutect2, varscan2
- PTPRR | c.1876G>A p.D626N | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs202061700; called by muse, mutect2, varscan2
- PTPRT | c.3778T>A p.F1260I | Missense Mutation (SNP) | VAF 52/97 reads (54%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV62005050, COSV62018797; called by muse, mutect2, varscan2
- RAB30 | c.67A>T p.T23S | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.95); PolyPhen probably damaging (0.999); catalogued as COSV52627433; called by muse, mutect2, varscan2
- RAG1 | c.1501C>T p.Q501* | Nonsense Mutation (SNP) | VAF 33/93 reads (35%) | catalogued as rs769349662, COSV55028079; called by muse, mutect2, varscan2
- REM1 | c.154C>T p.L52F | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.52); catalogued as COSV52428816; called by muse, mutect2, varscan2
- RP1 | c.5083G>A p.E1695K | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as COSV55120253; called by muse, mutect2
- RUBCN | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV56373869, COSV99583762; called by muse, mutect2, varscan2
- SAGE1 | c.676C>T p.R226* | Nonsense Mutation (SNP) | VAF 46/106 reads (43%) | catalogued as rs1556601244, COSV61011403; called by muse, mutect2, varscan2
- SAMD14 | c.892G>A p.E298K (on ENST00000330175 / NM_001257359.2; = p.E326K on NM_174920.4) | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV50304109; called by muse, mutect2, varscan2
- SASH3 | c.153+1G>A p.X51_splice | Splice Site (SNP) | VAF 18/19 reads (95%) | catalogued as COSV63556147; called by muse, mutect2, varscan2
- SCIN | c.1761G>A p.E587= (on ENST00000297029 / NM_001112706.3; = p.E340= on NM_033128.3) | Splice Region (SNP) | VAF 7/14 reads (50%) | catalogued as rs775783218, COSV51697486, COSV51698475; called by muse, mutect2, varscan2
- SEC23B | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs111758941, COSV52718128; called by muse, mutect2, varscan2
- SEPTIN14 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV66428702; called by muse, mutect2, varscan2
- SERPINB2 | c.616G>A p.G206R | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs371932536, COSV55093294; called by muse, mutect2, varscan2
- SLC34A2 | c.2027G>A p.G676D | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV65943120; called by muse, mutect2, varscan2
- SLC6A1 | c.1635G>A p.M545I | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.815); catalogued as COSV55116493; called by muse, mutect2, varscan2
- SLCO2A1 | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.43); catalogued as rs747030503, COSV100188692, COSV60487005; called by muse, mutect2, varscan2
- SNCAIP | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54414501; called by muse, mutect2, varscan2
- SP140L | c.551G>A p.R184K | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV54748266; called by muse, mutect2, varscan2
- SPEN | c.7303C>T p.P2435S | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV65366550; called by muse, mutect2, varscan2
- SPHKAP | c.970C>T p.H324Y | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60884498; called by muse, mutect2, varscan2
- SPIRE2 | c.1286C>T p.P429L | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs138861470, COSV65556909; called by muse, mutect2, varscan2
- SREBF2 | c.118G>C p.G40R | Missense Mutation (SNP) | VAF 71/182 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV63331751; called by muse, mutect2, varscan2
- ST18 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.097); catalogued as rs186302939, COSV52502898; called by muse, mutect2, varscan2
- STAB2 | c.5534G>A p.G1845E | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.343); catalogued as rs756586703, COSV101185600, COSV66341787; called by muse, mutect2, varscan2
- STARD8 | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 17/17 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV52927257; called by muse, mutect2, varscan2
- STIM1 | c.1562C>T p.S521L | Missense Mutation (SNP) | VAF 81/172 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as rs745539009, COSV56157055; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- STK11IP | c.232C>T p.L78F | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV55252989; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.3026G>A p.G1009E | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as rs368819440; called by muse, mutect2, varscan2
- SYK | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748067972, COSV65326644; called by muse, mutect2, varscan2
- SYNE1 | c.15094C>T p.L5032F (on ENST00000367255 / NM_182961.4; = p.L4961F on NM_033071.3) | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.399); catalogued as COSV55024113; called by muse, mutect2, varscan2
- SYNE1 | c.6767C>T p.S2256F (on ENST00000367255 / NM_182961.4; = p.S2263F on NM_033071.3) | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV55024132; called by muse, mutect2, varscan2
- SYT17 | c.425C>T p.S142L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as rs747054767, COSV62546248; called by muse, mutect2, varscan2
- SYT4 | c.1261G>A p.V421M | Missense Mutation (SNP) | VAF 61/194 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs775106428, COSV54901695; called by muse, mutect2, varscan2
- SYTL2 | c.1323T>G p.N441K | Missense Mutation (SNP) | VAF 33/210 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV60360598; called by muse, mutect2, varscan2
- TBL2 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV59787514; called by muse, mutect2, varscan2
- TENM3 | c.2050G>A p.D684N | Missense Mutation (SNP) | VAF 100/217 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs1220269708, COSV69318963; called by muse, mutect2, varscan2
- TESMIN | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.108); catalogued as COSV54835085; called by muse, mutect2, varscan2
- THEMIS | c.587G>A p.R196K | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV64071904, COSV64072103; called by muse, mutect2, varscan2
- TMEM74B | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.548); catalogued as COSV67892071; called by muse, mutect2, varscan2
- TNIK | c.3976T>A p.F1326I | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52695659; called by muse, mutect2, varscan2
- TNR | c.2440G>A p.E814K | Missense Mutation (SNP) | VAF 52/65 reads (80%) | SIFT tolerated (0.84); PolyPhen benign (0.065); catalogued as COSV54896188; called by muse, mutect2, varscan2
- TRAPPC8 | c.44C>T p.S15F | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as rs777600912, COSV51973798; called by muse, mutect2, varscan2
- TREM2 | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 164/216 reads (76%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as COSV58294577; called by muse, mutect2, varscan2
- TRMT44 | c.1532C>T p.S511F | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as COSV67663989; called by muse, mutect2, varscan2
- TTBK2 | c.3542C>T p.S1181L | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.788); catalogued as rs748766632, COSV51157748; called by muse, mutect2, varscan2
- TTC5 | c.574C>T p.L192F | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.901); catalogued as COSV51870510, COSV51871424; called by mutect2, varscan2
- TUBAL3 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 66/159 reads (42%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.19); catalogued as rs370481213, COSV66814422; called by muse, mutect2, varscan2
- UNC79 | c.5002C>T p.P1668S (on ENST00000393151 / NM_001346218.2; = p.P1491S on NM_020818.5) | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV56402765; called by muse, mutect2
- UPF3A | c.982G>A p.G328S | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs139333511, COSV60896176; called by muse, mutect2
- USF3 | c.3026C>T p.S1009F | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.9); catalogued as rs1444463362, COSV57077287; called by muse, mutect2, varscan2
- USH2A | c.13180G>A p.D4394N | Missense Mutation (SNP) | VAF 33/41 reads (80%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV56392869; called by muse, mutect2, varscan2
- VPS13D | c.3200C>T p.S1067L | Missense Mutation (SNP) | VAF 53/121 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV50681578; called by muse, mutect2, varscan2
- WNT11 | c.621G>A p.M207I | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.14); catalogued as COSV59444207; called by muse, mutect2, varscan2
- XKR7 | c.572G>A p.G191D | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV73813465; called by muse, mutect2, varscan2
- ZC3HAV1 | c.2152G>A p.E718K | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs767120888, COSV54297624; called by muse, mutect2, varscan2
- ZFP64 | c.1081C>T p.H361Y | Missense Mutation (SNP) | VAF 58/147 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53801020; called by muse, mutect2, varscan2
- ZNF234 | c.1169A>T p.H390L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs753238363, COSV70604230; called by muse, mutect2
- ZNF234 | c.1171C>A p.Q391K | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.407); catalogued as COSV70604234; called by muse, mutect2
- ZNF343 | c.565A>T p.T189S | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.386); catalogued as COSV53854598; called by muse, mutect2, varscan2
- ZNF391 | c.476A>C p.H159P | Missense Mutation (SNP) | VAF 38/347 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55124974; called by muse, mutect2, varscan2
- ZNF608 | c.3830A>T p.K1277I | Missense Mutation (SNP) | VAF 174/307 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.692); catalogued as COSV60439202, COSV60439320; called by muse, mutect2, varscan2
- ZNF646 | c.4619del p.Y1540Sfs*8 | Frame Shift Del (DEL) | VAF 35/102 reads (34%) | catalogued as COSV54925275; called by mutect2, pindel, varscan2
- ZNF831 | c.3320C>T p.P1107L | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV64045089; called by muse, mutect2, varscan2
- ACSM4 | c.1178G>A p.G393E | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATG4C | c.1043A>C p.Y348S | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- C6 | c.96G>A p.W32* | Nonsense Mutation (SNP) | VAF 24/62 reads (39%) | called by muse, mutect2, varscan2
- FIGNL1 | c.1709_1710delinsA p.A570Dfs*7 | Frame Shift Del (DEL) | VAF 33/92 reads (36%) | called by pindel, varscan2*
- HSPA5 | c.1312C>T p.P438S | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- IGHMBP2 | c.2435del p.P812Lfs*19 | Frame Shift Del (DEL) | VAF 29/37 reads (78%) | called by mutect2, varscan2
- IGHV3-64 | c.301C>T p.L101F | Missense Mutation (SNP) | VAF 114/262 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- PCDH10 | c.307_321dup p.L103_Q107dup | In Frame Ins (INS) | VAF 26/74 reads (35%) | called by mutect2, varscan2
- SLC35F4 | c.19G>A p.D7N | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SYNDIG1L | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ACP1 | c.465G>A p.E155= | Silent (SNP) | VAF 45/134 reads (34%) | catalogued as rs150164591; called by muse, mutect2, varscan2
- ACVR1B | c.966C>T p.I322= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as rs763203996, COSV57775230; called by muse, mutect2, varscan2
- ADAMTS18 | c.1761C>T p.P587= | Silent (SNP) | VAF 92/224 reads (41%) | catalogued as COSV51422938, COSV51423295; called by muse, mutect2, varscan2
- ADAMTS18 | c.1539G>A p.Q513= | Silent (SNP) | VAF 45/87 reads (52%) | catalogued as COSV51422943; called by muse, mutect2, varscan2
- ALPK3 | c.2661G>A p.P887= | Silent (SNP) | VAF 39/64 reads (61%) | catalogued as rs142125273; called by muse, mutect2, varscan2
- ALPK3 | c.4329C>T p.I1443= | Silent (SNP) | VAF 47/76 reads (62%) | catalogued as COSV51939584; called by muse, mutect2, varscan2
- ASTN2 | c.528C>T p.S176= | Silent (SNP) | VAF 36/102 reads (35%) | catalogued as COSV57771990, COSV57816815; called by muse, varscan2
- BMPR1B | c.576C>T p.L192= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as rs976654547, COSV52781758, COSV99215229; called by muse, mutect2, varscan2
- C10orf53 | c.130C>T p.L44= | Silent (SNP) | VAF 30/56 reads (54%) | catalogued as rs775376184, COSV100934951, COSV65108121; called by muse, mutect2, varscan2
- C12orf4 | c.1074C>T p.F358= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV54209664; called by muse, mutect2, varscan2
- CACNA2D3 | c.2892G>A p.Q964= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as COSV55580910; called by muse, mutect2, varscan2
- CATSPERB | c.1905C>T p.V635= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV56435062; called by muse, mutect2, varscan2
- CATSPERD | c.1302C>T p.S434= | Silent (SNP) | VAF 23/80 reads (29%) | catalogued as COSV58467493; called by muse, mutect2, varscan2
- CBX7 | c.468C>T p.F156= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV53359858; called by muse, mutect2, varscan2
- CC2D1A | c.1881C>T p.F627= | Silent (SNP) | VAF 38/99 reads (38%) | catalogued as rs766483368, COSV58784138; ClinVar: likely benign; called by muse, mutect2, varscan2
- CDH6 | c.2094C>T p.F698= | Silent (SNP) | VAF 31/57 reads (54%) | catalogued as COSV54065182; called by muse, mutect2, varscan2
- CEACAM1 | c.444C>T p.S148= | Silent (SNP) | VAF 108/265 reads (41%) | catalogued as COSV50732621; called by muse, mutect2, varscan2
- CENPF | c.2676T>C p.T892= | Silent (SNP) | VAF 21/94 reads (22%) | catalogued as COSV65278965; called by muse, mutect2, varscan2
- CHL1 | c.477C>T p.L159= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as COSV56605994; called by muse, mutect2, varscan2
- CMTR2 | c.630C>T p.I210= | Silent (SNP) | VAF 56/120 reads (47%) | catalogued as COSV57604997; called by muse, mutect2, varscan2
- CNTNAP5 | c.2121C>T p.H707= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as COSV70511563; called by muse, mutect2, varscan2
- COPA | c.2898C>T p.G966= | Silent (SNP) | VAF 46/224 reads (21%) | catalogued as COSV54109396; called by muse, mutect2, varscan2
- CORO1C | c.1383T>C p.R461= | Silent (SNP) | VAF 63/156 reads (40%) | catalogued as COSV54598992; called by muse, mutect2, varscan2
- CSMD1 | c.8283G>A p.V2761= (on ENST00000520002; = p.V2760= on NM_033225.6) | Silent (SNP) | VAF 29/39 reads (74%) | catalogued as COSV59340736; called by muse, mutect2, varscan2
- DAND5 | c.471C>T p.P157= | Silent (SNP) | VAF 71/177 reads (40%) | catalogued as rs751930538; called by muse, mutect2, varscan2
- DCD | c.315C>T p.V105= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs954138007, COSV53202426; called by muse, mutect2, varscan2
- DENND1A | c.1476C>T p.V492= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as COSV65332378; called by muse, mutect2, varscan2
- DHCR7 | c.435C>T p.I145= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as rs941214871, COSV62795865; called by muse, mutect2, varscan2
- DMBT1 | c.3205C>T p.L1069= (on ENST00000338354 / NM_001377530.1; = p.L570= on NM_004406.3) | Silent (SNP) | VAF 59/143 reads (41%) | catalogued as rs1180161694, COSV57561097; called by muse, mutect2, varscan2
- DNAH17 | c.10210C>T p.L3404= | Silent (SNP) | VAF 31/117 reads (26%) | catalogued as rs1281646129, COSV67760960; called by muse, mutect2, varscan2
- DNAH3 | c.7578C>T p.I2526= | Silent (SNP) | VAF 31/57 reads (54%) | catalogued as rs1237815708, COSV54512892; called by muse, mutect2, varscan2
- EGFLAM | c.1380C>T p.I460= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as rs368435301; called by muse, mutect2, varscan2
- EIF2AK4 | c.1191C>T p.I397= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV55474010; called by muse, mutect2, varscan2
- EPHA8 | c.2271C>T p.V757= | Silent (SNP) | VAF 10/37 reads (27%) | called by muse, mutect2, varscan2
- ETS2 | c.885C>T p.S295= | Silent (SNP) | VAF 33/74 reads (45%) | catalogued as COSV62874362; called by muse, mutect2, varscan2
- EXTL3 | c.1299C>T p.I433= | Silent (SNP) | VAF 30/33 reads (91%) | catalogued as rs1432191459, COSV55040119, COSV55040440; called by muse, mutect2, varscan2
- F13B | c.381G>A p.G127= | Silent (SNP) | VAF 18/32 reads (56%) | catalogued as rs1281502925, COSV66375630; called by muse, mutect2, varscan2
- FCN2 | c.120G>T p.L40= | Silent (SNP) | VAF 40/110 reads (36%) | catalogued as COSV52478716, COSV52479488; called by muse, mutect2, varscan2
- GCN1 | c.5766C>T p.I1922= | Silent (SNP) | VAF 48/97 reads (49%) | catalogued as COSV56114600; called by muse, mutect2, varscan2
- GPC2 | c.142C>T p.L48= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as rs771055519, COSV52786493; called by muse, mutect2, varscan2
- GPRC5C | c.915C>T p.I305= (on ENST00000652232; = p.I260= on NM_018653.4) | Silent (SNP) | VAF 50/149 reads (34%) | catalogued as rs1010914923, COSV61237935; called by muse, mutect2, varscan2
- GRID1 | c.684C>T p.I228= | Silent (SNP) | VAF 67/139 reads (48%) | catalogued as COSV60052331; called by muse, mutect2, varscan2
- GRM1 | c.1536C>T p.I512= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as COSV51313576; called by muse, mutect2, varscan2
- HGD | c.1059G>A p.K353= | Silent (SNP) | VAF 48/132 reads (36%) | catalogued as COSV52201327; called by muse, mutect2, varscan2
- IDE | c.2496C>T p.I832= | Silent (SNP) | VAF 86/172 reads (50%) | catalogued as rs758600182, COSV56427254; called by muse, mutect2, varscan2
- IGHE | c.72C>T p.S24= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs1555457222; called by muse, mutect2, varscan2
- IL37 | c.30G>A p.V10= | Silent (SNP) | VAF 39/79 reads (49%) | catalogued as rs868059043, COSV54489914; called by muse, mutect2, varscan2
- ITGAV | c.2241C>T p.I747= | Silent (SNP) | VAF 38/61 reads (62%) | catalogued as COSV53718787; called by muse, mutect2, varscan2
- ITGAX | c.948G>A p.V316= | Silent (SNP) | VAF 73/124 reads (59%) | catalogued as COSV51651338; called by muse, mutect2, varscan2
- KCNJ1 | c.633C>T p.I211= | Silent (SNP) | VAF 22/24 reads (92%) | catalogued as COSV60662776; called by muse, mutect2, varscan2
- KCNJ15 | c.504C>T p.I168= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as rs140458855; called by muse, mutect2, varscan2
- KIR2DL4 | c.1041C>T p.F347= (on ENST00000396284; = p.F273= on NM_001080770.2) | Silent (SNP) | VAF 128/309 reads (41%) | catalogued as COSV100428731; called by muse, mutect2, varscan2
- KRT73 | c.1404A>G p.T468= | Silent (SNP) | VAF 23/46 reads (50%) | catalogued as COSV59841651; called by muse, mutect2, varscan2
- LDLR | c.177C>T p.S59= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV52945894; called by muse, mutect2, varscan2
- LTBP1 | c.504C>T p.V168= | Silent (SNP) | VAF 53/138 reads (38%) | catalogued as COSV63197775; called by muse, mutect2, varscan2
- LTBP2 | c.744G>A p.R248= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as COSV100000910, COSV56214020; called by muse, mutect2, varscan2
- MEAK7 | c.162C>T p.V54= | Silent (SNP) | VAF 88/168 reads (52%) | catalogued as rs369348901, COSV59145535; called by muse, mutect2, varscan2
- MIB1 | c.789T>C p.S263= | Silent (SNP) | VAF 105/215 reads (49%) | catalogued as COSV55094835; called by muse, mutect2, varscan2
- MIB2 | c.1158C>T p.V386= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs753942002, COSV61757478; called by muse, mutect2, varscan2
- MMP7 | c.387G>A p.V129= | Silent (SNP) | VAF 104/315 reads (33%) | catalogued as COSV52773134; called by muse, mutect2, varscan2
- MTHFD1 | c.2064C>T p.S688= | Silent (SNP) | VAF 50/94 reads (53%) | catalogued as rs773494969, COSV53703734; called by muse, mutect2, varscan2
- MYBPC2 | c.162C>T p.F54= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as rs1446207571, COSV63099820; called by muse, mutect2, varscan2
- NCOR2 | c.2916C>G p.A972= | Silent (SNP) | VAF 82/216 reads (38%) | catalogued as COSV62304389; called by muse, mutect2, varscan2
- NEIL3 | c.936C>T p.S312= | Silent (SNP) | VAF 56/125 reads (45%) | catalogued as rs138744063, COSV52811364; called by muse, mutect2, varscan2
- NMBR | c.1035C>T p.S345= | Silent (SNP) | VAF 24/51 reads (47%) | catalogued as COSV57803278; called by muse, mutect2, varscan2
- NXPH4 | c.565C>T p.L189= | Silent (SNP) | VAF 30/76 reads (39%) | catalogued as COSV61075309; called by muse, mutect2, varscan2
- OR2L13 | c.696G>A p.G232= | Silent (SNP) | VAF 17/92 reads (18%) | catalogued as rs1028262792, COSV63554414; called by muse, mutect2, varscan2
- OR2T4 | c.975G>A p.R325= | Silent (SNP) | VAF 23/126 reads (18%) | catalogued as COSV63545117; called by muse, mutect2, varscan2
- OR4C15 | c.129C>T p.I43= | Silent (SNP) | VAF 50/67 reads (75%) | catalogued as COSV58951506, COSV58955266; called by muse, mutect2, varscan2
- OR4K13 | c.843C>T p.L281= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV59860821; called by muse, mutect2, varscan2
- OR4K5 | c.897G>A p.R299= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs749816085, COSV60003526; called by muse, mutect2, varscan2
- ORC1 | c.1920C>T p.P640= | Silent (SNP) | VAF 36/87 reads (41%) | catalogued as COSV100856770, COSV65365161; called by muse, mutect2, varscan2
- PLXNC1 | c.3714C>T p.F1238= | Silent (SNP) | VAF 37/79 reads (47%) | catalogued as rs921647884, COSV51580704, COSV51583787; called by muse, mutect2, varscan2
- PRB4 | c.90C>T p.F30= | Silent (SNP) | VAF 59/150 reads (39%) | catalogued as rs1371823694, COSV54400160, COSV54400579; called by muse, mutect2, varscan2
- PSD4 | c.2022C>T p.F674= | Silent (SNP) | VAF 35/61 reads (57%) | catalogued as COSV55530089; called by muse, mutect2, varscan2
- PTPRD | c.3609C>T p.F1203= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV61973024, COSV61980744; called by muse, mutect2, varscan2
- RAC2 | c.318C>T p.P106= | Silent (SNP) | VAF 35/74 reads (47%) | catalogued as rs770222890, COSV50775461; called by muse, mutect2, varscan2
- RIC1 | c.3780C>T p.S1260= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV52615355; called by muse, mutect2
- SDC3 | c.759C>T p.T253= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV59580713; called by muse, mutect2, varscan2
- SETX | c.6450C>T p.I2150= | Silent (SNP) | VAF 59/135 reads (44%) | catalogued as COSV56394424; called by muse, mutect2, varscan2
- SF3B1 | c.99C>T p.L33= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as rs143444124; called by muse, mutect2, varscan2
- SH3RF3 | c.1519C>T p.L507= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV58695190, COSV99079872; called by muse, mutect2, varscan2
- SIGLEC11 | c.1224G>A p.Q408= | Silent (SNP) | VAF 36/73 reads (49%) | catalogued as COSV70222166; called by muse, mutect2, varscan2
- SKAP1 | c.855G>A p.E285= | Silent (SNP) | VAF 53/128 reads (41%) | catalogued as COSV61152624; called by muse, mutect2, varscan2
- SMG1 | c.10629G>T p.R3543= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as rs781441609; called by muse, mutect2, varscan2
- SPIB | c.267C>T p.L89= | Silent (SNP) | VAF 51/159 reads (32%) | catalogued as rs1009054822, COSV54532575; called by muse, mutect2, varscan2
- STYXL2 | c.771G>A p.K257= | Silent (SNP) | VAF 28/129 reads (22%) | catalogued as COSV54809915; called by muse, mutect2, varscan2
- SYK | c.1770G>C p.R590= | Silent (SNP) | VAF 11/26 reads (42%) | called by muse, mutect2, varscan2
- SYNDIG1L | c.105G>A p.Q35= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV59047539; called by muse, mutect2, varscan2
- TECTA | c.5604C>T p.I1868= | Silent (SNP) | VAF 42/47 reads (89%) | catalogued as COSV50802386; called by muse, mutect2, varscan2
- TENM4 | c.3765C>T p.F1255= | Silent (SNP) | VAF 48/166 reads (29%) | catalogued as COSV53619087; called by muse, mutect2, varscan2
- TSC2 | c.528C>T p.F176= | Silent (SNP) | VAF 173/300 reads (58%) | catalogued as COSV54779540; called by muse, varscan2
- UBQLNL | c.222C>T p.F74= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV66494556; called by muse, mutect2, varscan2
- UNK | c.1608C>T p.F536= | Silent (SNP) | VAF 46/147 reads (31%) | catalogued as rs762888859, COSV53147164; called by muse, mutect2, varscan2
- WFDC10A | c.48G>A p.L16= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as COSV58097869; called by muse, mutect2, varscan2
- ZFYVE26 | c.5034C>T p.P1678= | Silent (SNP) | VAF 60/145 reads (41%) | catalogued as COSV61333439; called by muse, varscan2
- ZNF329 | c.831C>T p.H277= | Silent (SNP) | VAF 71/127 reads (56%) | catalogued as COSV63773392; called by muse, mutect2, varscan2
- ZNF835 | c.675C>A p.A225= | Silent (SNP) | VAF 18/26 reads (69%) | catalogued as COSV73379745; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505774 T>A | 5'Flank (SNP) | VAF 26/56 reads (46%) | called by muse, mutect2, varscan2
- NDUFA13 | chr19:19516218 G>A | 5'Flank (SNP) | VAF 30/77 reads (39%) | catalogued as rs774370255, COSV53063591; called by muse, mutect2, varscan2
- PPP1R9A | c.2758-2038C>T | Intron (SNP) | VAF 8/17 reads (47%) | catalogued as rs1324814104, COSV99195320; called by muse, mutect2, varscan2
- RN7SL484P | chr15:99792506 G>A | 3'Flank (SNP) | VAF 96/151 reads (64%) | catalogued as rs776754220; called by muse, mutect2, varscan2
- RPL23AP82 | n.520G>A | RNA (SNP) | VAF 25/61 reads (41%) | called by muse, mutect2, varscan2
- TANGO2 | c.56+192C>T | Intron (SNP) | VAF 47/156 reads (30%) | called by muse, mutect2, varscan2
- WASF4P | n.770C>T | RNA (SNP) | VAF 66/73 reads (90%) | called by muse, mutect2, varscan2
- ZNF467 | chr7:149776382 G>A | 5'Flank (SNP) | VAF 12/34 reads (35%) | catalogued as rs543380198, COSV50489282; called by muse, mutect2, varscan2
